Somatic mutation profile of tumor specimen MP2PRT-PARXNY-TMP1-A (aliquot MP2PRT-PARXNY-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARXNY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,640 days).
Specimen MP2PRT-PARXNY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2fb8e2f-e734-4145-8bd8-2b813f60409f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXNY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXNY-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7d45ec-1aab-4060-aab1-d74a445601d4

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 3, Frame Shift Del 2, RNA 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 136/320 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 188/444 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs772877568, COSV53352720; called by muse, mutect2, varscan2
- BZW2 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1377038665; called by muse, mutect2
- FAM166C | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56604075; called by muse, mutect2, varscan2
- FAM178B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 265/575 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as rs1393173359; called by muse, mutect2, varscan2
- FLG | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 176/420 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as rs779690124, COSV64239340; called by muse, mutect2
- IRF1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 39/334 reads (12%) | catalogued as COSV55376240; called by muse, mutect2, varscan2
- MTUS1 | c.3635C>T p.S1212L (on ENST00000262102 / NM_001363061.1; = p.S378L on NM_020749.4) | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1264098528; called by muse, mutect2, varscan2
- MXRA5 | c.2158C>A p.Q720K | Missense Mutation (SNP) | VAF 211/449 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV99475799; called by muse, mutect2, varscan2
- PEG3 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 307/698 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55638723; called by muse, mutect2, varscan2
- PLEKHA1 | c.743A>C p.Q248P | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV64570714; called by muse, mutect2, varscan2
- RYR3 | c.10621G>A p.E3541K (on ENST00000389232; = p.E3542K on NM_001036.6) | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as rs1195837601, COSV101213138, COSV101213150; called by muse, mutect2, varscan2
- SEMA5B | c.3288G>A p.M1096I | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs1388870670; called by muse, mutect2, varscan2
- SGK2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 136/280 reads (49%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs140923021; called by muse, mutect2, varscan2
- SLC22A2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as rs771411024, COSV65267513; called by muse, mutect2, varscan2
- SPRN | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 203/479 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs901005986; called by muse, mutect2, varscan2
- TJP1 | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 252/594 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as rs539329069, COSV62039877; called by muse, mutect2, varscan2
- TP63 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 183/426 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754080925, COSV53223792; called by muse, mutect2, varscan2
- ZBTB9 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 238/588 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs762962868; called by muse, mutect2, varscan2
- BCO2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C8A | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GOLGA6L9 | c.80A>T p.K27I | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRMDA | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.425); called by muse, mutect2
- LRRC9 | c.1029del p.K343Nfs*2 | Frame Shift Del (DEL) | VAF 69/189 reads (37%) | called by mutect2, pindel, varscan2
- MCPH1 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 172/351 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8B3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PHF21A | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 136/293 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTPRJ | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 121/270 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.12804G>A p.M4268I | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC9A4 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM5 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 180/388 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TSPYL2 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 186/424 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.66043C>T p.P22015S (on ENST00000591111; = p.P14591S on NM_003319.4) | Missense Mutation (SNP) | VAF 154/310 reads (50%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCAN | c.9752G>A p.R3251K | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWCE | c.24_25del p.A9Rfs*101 | Frame Shift Del (DEL) | VAF 212/549 reads (39%) | called by mutect2, pindel*, varscan2*
- ZNF492 | c.1535A>G p.N512S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C1orf87 | c.87C>T p.Y29= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as rs780695243; called by muse, mutect2, varscan2
- COL3A1 | c.1398G>A p.K466= | Silent (SNP) | VAF 129/303 reads (43%) | catalogued as rs781761966; called by muse, mutect2, varscan2
- COL4A3 | c.804C>T p.G268= | Silent (SNP) | VAF 139/288 reads (48%) | catalogued as rs567238530; called by muse, mutect2, varscan2
- GEMIN5 | c.435G>A p.Q145= | Silent (SNP) | VAF 61/172 reads (35%) | catalogued as COSV53563555; called by muse, mutect2, varscan2
- INHBC | c.588C>T p.T196= | Silent (SNP) | VAF 207/430 reads (48%) | catalogued as COSV59004477; called by muse, mutect2, varscan2
- MASP2 | c.909G>A p.P303= | Silent (SNP) | VAF 98/232 reads (42%) | called by muse, mutect2, varscan2
- NOMO1 | c.3294C>T p.F1098= | Silent (SNP) | VAF 207/519 reads (40%) | called by muse, mutect2, varscan2
- PLA2G4F | c.306C>T p.I102= | Silent (SNP) | VAF 145/344 reads (42%) | called by muse, mutect2, varscan2
- PPP1R13B | c.1020G>A p.S340= | Silent (SNP) | VAF 174/409 reads (43%) | catalogued as rs201455560; called by muse, mutect2, varscan2
- PRAMEF14 | c.1080G>A p.Q360= | Silent (SNP) | VAF 172/657 reads (26%) | called by muse, mutect2, varscan2
- SERPINB11 | c.435G>A p.T145= | Silent (SNP) | VAF 87/301 reads (29%) | catalogued as rs367579501; called by muse, mutect2, varscan2
- TEKT1 | c.909C>T p.I303= | Silent (SNP) | VAF 155/364 reads (43%) | catalogued as rs1340523327; called by muse, mutect2, varscan2
- ZNF630 | c.1827C>T p.F609= | Silent (SNP) | VAF 128/306 reads (42%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3935-29G>A | Intron (SNP) | VAF 158/346 reads (46%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.870G>A | RNA (SNP) | VAF 44/267 reads (16%) | catalogued as rs3111685, COSV71422429; called by muse, mutect2, varscan2
- ANO10 | c.1915-5798C>T | Intron (SNP) | VAF 149/322 reads (46%) | called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins GGTCC | 3'Flank (INS) | VAF 55/109 reads (50%) | called by mutect2, pindel, varscan2
- OBSCN | c.11659+3574G>A | Intron (SNP) | VAF 181/420 reads (43%) | catalogued as rs192073811; called by muse, mutect2, varscan2
